Somatic mutation profile of tumor specimen TCGA-XU-A92Z-01A (aliquot TCGA-XU-A92Z-01A-11D-A423-09) from TCGA case TCGA-XU-A92Z, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymic carcinoma, NOS; Tissue or organ of origin: Thymus; Age at diagnosis: 77.0 years (28,117 days).
Specimen TCGA-XU-A92Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4c8e469e-77cc-4175-93f8-08a66a59052a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XU-A92Z-10A (Blood Derived Normal), aliquot TCGA-XU-A92Z-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e543dfe0-65c0-4b64-83a0-fecb8725ad0f

The open-access MAF lists 22 somatic variants for this specimen: 19 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, 5'Flank 1, Splice Site 1, Silent 1, Frame Shift Del 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP1A2 | c.1091C>T p.T364M | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1553244881, rs796052276, CM113792, COSV63402372; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 21/73 reads (29%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADCY3 | c.3184G>A p.D1062N | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771218760; called by muse, mutect2, varscan2
- ERVW-1 | c.1307G>A p.G436E | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs1423652181; called by muse, mutect2, varscan2
- GALNT9 | c.1459C>T p.R487W (on ENST00000328957 / NM_001122636.2; = p.R121W on NM_021808.3) | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.54); catalogued as rs772372545; called by muse, mutect2, varscan2
- MUC16 | c.3307G>A p.V1103I | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs533537740; called by muse, mutect2, varscan2
- NF2 | c.481G>T p.G161* | Nonsense Mutation (SNP) | VAF 17/39 reads (44%) | catalogued as COSV58524525; called by muse, mutect2, varscan2
- RFC5 | c.926+1G>T p.X309_splice | Splice Site (SNP) | VAF 6/44 reads (14%) | catalogued as COSV57477825; called by muse, mutect2
- ZNF544 | c.1522G>A p.V508I | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs768920049, COSV54134912; called by muse, varscan2
- A4GALT | c.914C>A p.P305Q | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANGPTL6 | c.622C>G p.R208G | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAJC8 | c.373G>T p.A125S | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- EVI5L | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GBA2 | c.141T>A p.S47R | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, varscan2
- GFI1B | c.175A>C p.N59H | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC23A1 | c.329G>A p.S110N | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLCO2A1 | c.1445C>T p.A482V | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2
- SMARCA4 | c.3383G>T p.G1128V | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF714 | c.884del p.N295Tfs*11 | Frame Shift Del (DEL) | VAF 14/51 reads (27%) | called by mutect2, pindel, varscan2
- CORO7 | c.1101C>T p.T367= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as rs769559140, COSV52028779; called by muse, mutect2
- AP000769.3 | chr11:65502293 ins T | 5'Flank (INS) | VAF 37/106 reads (35%) | called by mutect2, pindel, varscan2
- Z82190.2 | c.1787-21780G>T | Intron (SNP) | VAF 11/42 reads (26%) | called by muse, mutect2, varscan2
